Surgical pathology report (de-identified scan), TCGA case TCGA-F4-6806, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Asterand, specimen TCGA-F4-6806-01A (Primary Tumor).

[page 1 of 2]
Formatted Path Report

LARGE INTESTINE TISSUE
CHECKLIST

Specimen type: Excision of tumor
Specimen size: Not specified
Tumor site: Sigmoid colon
Tumor size: 7 x 6 x 1.7 cm
Tumor features: Exophytic (polypoid)
Histologic type: Adenocarcinoma
Histologic grade: Moderately
differentiated
Tumor extent: Muscularis propria
Lymph nodes: 0/5 positive for
metastasis (Regional 0/5)
Margins: Uninvolved
Evidence of neo-adjuvant treatment:
Not specified
Additional pathologic findings: Not
specified
Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file 0ce00a0f-4900-42e2-98ca-30c75ce5618f (TCGA-F4-6806.73742089-F64F-41FC-84E2-BC9B59D29C02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).